Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZQ-06A from TCGA case TCGA-FS-A1ZQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 42.2 years (15,398 days).
Specimen TCGA-FS-A1ZQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.fbffdae0-9068-4ca8-87d4-237b6e6ebf75.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a787249-4cfa-4e14-a1ea-4457a951816c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,784; copy number 2: 37,985; copy number 3: 940; copy number 4: 30; copy number 5: 39; copy number 6: 19; copy number 8: 14; copy number 11: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZQ-06A-11D-A191-01): tumor purity 0.78, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 79 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:46,383,652–46,876,784, 1 gene, copy number 8 (within-gene range 1–8): AC008014.1.
- chr12:46,537,502–47,279,021, 13 genes, copy number 8: AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4.
- chr12:67,709,047–68,234,686, 9 genes, copy number 6 (within-gene range 1–6): LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:68,686,951–68,745,809, 1 gene, copy number 11 (within-gene range 4–11): NUP107.
- chr12:68,746,125–70,920,738, 45 genes, copy number 5–11 (within-gene range 1–11): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:80,935,736–81,869,046, 9 genes, copy number 6: MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1.
- chr12:86,599,578–86,838,998, 1 gene, copy number 6 (within-gene range 1–6): AC010196.1.

Autosomal genes at a single copy (total copy number 1): 18,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
